Gene-level copy-number profile of tumor specimen ALCH-ADR8-TTP1-A from ALCHEMIST case ALCH-ADR8, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 44.0 years (16,080 days).
Specimen ALCH-ADR8-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 848a813e-40fe-48dd-a11d-458de8f21d59.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADR8-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/792a80fa-4b62-4ece-b242-bda08b3f47bc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 32; copy number 1: 2,343; copy number 2: 49,334; copy number 3: 6,678; copy number 4: 7; copy number 5: 3; copy number 6: 3; copy number 15: 1.

Homozygous deletions (total copy number 0; autosomes only): 32 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:43,525,187–43,623,666, 1 gene: PTPRF.
- chr2:127,625,997–127,681,786, 3 genes (within-gene range 0–2): AC010976.2, LIMS2, GPR17.
- chr2:232,343,116–232,351,309, 2 genes (within-gene range 0–2): NRBF2P6, ECEL1P3.
- chr2:232,442,034–232,447,418, 1 gene: DIS3L2P1.
- chr2:232,520,388–232,548,115, 3 genes (within-gene range 0–2): PRSS56, CHRND, CHRNG.
- chr9:21,802,636–22,128,103, 14 genes (within-gene range 0–1): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr17:79,074,824–79,088,599, 1 gene: ENGASE.
- chr22:29,705,256–29,770,413, 7 genes: AC004882.1, AC004882.2, CABP7, ZMAT5, Y_RNA, AC004882.3, UQCR10.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:136,844,415–136,860,799, 3 genes, copy number 6 (within-gene range 3–6): AJM1, PHPT1, MAMDC4.
- chr20:62,877,738–62,937,952, 2 genes, copy number 5: DIDO1, AL117379.1.
- chr22:20,320,739–20,354,387, 2 genes, copy number 5–15 (within-gene range 2–15): AC007663.3, AC007731.5.

Autosomal genes at a single copy (total copy number 1): 2,325. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
